Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3821, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3821-01A (Primary Tumor).

Diagnosis

This concerns a right hemicolectomy preparation with a tubulovillous adenoma in the cecum, with mild dysplasia of the cylindrical epithelium, with peritumorous, chronic recidivated concomitant inflammation with acute inflammatory activity. There is a second tubulovillous colon mucus adenoma in the colon ascendens with mild dysplasia of the cylindrical epithelium and reactive concomitant inflammation, with tubular adenomas in the area of this second one, with a mucinous carcinoma (corresponding to a mucus-forming adenocarcinoma), with moderate to slight differentiation – corresponding to histopathological differentiation grade 2-3, with tubulovillous adenoma sections on the surface, with tumor infiltration of the colon wall layers to the tunica muscularis, with peritumorous chronic recidivated concomitant inflammation, with moderate chronic lymphadenitis of the tumor-free local lymph nodes (0/13) and with tumor-free overview slices from all other preparation sections described.

According to the preparation sections at hand, the spreading of the mucinous carcinoma in the colon transversum corresponds to a tumor stage of pT2, pN0, MX, R0.

Tumor classification

ICDO-DA M-8480/3

Source: NCI Genomic Data Commons file 367a621f-7ebb-473c-a8ba-1fd89b428ed6 (TCGA-AA-3821.F65818AC-707F-432E-B5F5-0BE1405074E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).